CCDI case PBCETK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/218dbfe4-b213-4491-8544-44e9709947bb

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pinealoma: ICD-O-3 morphology code: 9360/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.1 years (5,883 days).

Biospecimens (3 samples)
- Sample 0DQ7V4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DQ7V7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQ7VB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
